CCDI case PBBPLH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/04bde4fd-bfa0-4d21-94df-13c752af6030

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,476 days).

Biospecimens (3 samples)
- Sample 0DEHN2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHNY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEHPJ: Tissue type: Tumor; Specimen type: Solid Tissue.
